Somatic mutation profile of tumor specimen TCGA-HR-A5NC-01A (aliquot TCGA-HR-A5NC-01A-11D-A27K-08) from TCGA case TCGA-HR-A5NC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-HR-A5NC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aca28098-2b7b-4a37-b3f6-cd7aaf89273c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HR-A5NC-10A (Blood Derived Normal), aliquot TCGA-HR-A5NC-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e739c528-13a0-4dab-a2d8-ab92d74cb224

The open-access MAF lists 73 somatic variants for this specimen: 47 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 25, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 399/734 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs778698150, COSV57055309; called by muse, mutect2, varscan2
- AC013489.1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs758082536, COSV99183828; called by muse, mutect2, varscan2
- ANO2 | c.2728C>T p.Q910* (on ENST00000356134 / NM_001278597.3; = p.Q914* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100499845; called by muse, mutect2
- AOC1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs201145932; called by muse, mutect2, varscan2
- ARHGAP39 | c.2609C>T p.P870L (on ENST00000276826 / NM_001308208.2; = p.P901L on NM_025251.2) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99430299; called by muse, mutect2, varscan2
- ATP2B3 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1557004138, COSV54860039; called by muse, mutect2, varscan2
- ATP6V0D2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV53416678, COSV53418240; called by muse, mutect2, varscan2
- BMP3 | c.607A>C p.T203P | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307214088, COSV99261396; called by muse, mutect2, varscan2
- BPIFB2 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as rs759562997, COSV99401162; called by muse, mutect2, varscan2
- CD300LF | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs778379503, COSV100042592; called by muse, mutect2, varscan2
- CFH | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV100808876; called by muse, mutect2, varscan2
- COL16A1 | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99593611; called by muse, mutect2, varscan2
- CYP11B2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs777780952, COSV100010673; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH3 | c.6103G>A p.E2035K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54505137; called by muse, mutect2, varscan2
- FSHR | c.140A>T p.N47I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100436595; called by muse, mutect2, varscan2
- GABRA6 | c.1299C>A p.N433K | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762067086, COSV99194077, COSV99194230; called by muse, mutect2, varscan2
- GZMH | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764634951, COSV53537509, COSV99361803; called by muse, mutect2, varscan2
- HKDC1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100664370; called by muse, mutect2, varscan2
- HTRA4 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780739972, COSV100205589; called by muse, mutect2, varscan2
- HYDIN | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879226385, COSV99862023; called by muse, mutect2, varscan2
- IFT46 | c.268C>A p.P90T (on ENST00000264021 / NM_001168618.2; = p.P141T on NM_020153.3) | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99870903; called by muse, mutect2, varscan2
- KCNB1 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870384; called by muse, mutect2, varscan2
- KDM5A | c.4505C>T p.S1502L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1285922080, COSV66997596; called by muse, mutect2, varscan2
- KLF15 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV99955068; called by muse, mutect2, varscan2
- KPRP | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1303958363, COSV64222826; called by muse, mutect2, varscan2
- LPL | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV100255317; called by muse, mutect2, varscan2
- LRCH2 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100406305; called by muse, mutect2, varscan2
- MORC4 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV99716813; called by muse, mutect2, varscan2
- MRNIP | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.385); catalogued as COSV99481295; called by muse, mutect2, varscan2
- MYLK | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100658540; called by muse, varscan2
- NME7 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV100890887; called by muse, mutect2, varscan2
- NOD2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100318230; called by muse, mutect2, varscan2
- NPAP1 | c.1488C>A p.D496E | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100274800; called by muse, mutect2, varscan2
- PGR | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as COSV54796576, COSV54805703; called by muse, mutect2, varscan2
- PRKG1 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV64805010; called by muse, varscan2
- RBM12B | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.101); catalogued as COSV101234477, COSV67897883; called by muse, mutect2, varscan2
- ROS1 | c.5785C>T p.P1929S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1420331738, COSV100876514; called by muse, mutect2, varscan2
- SLC15A2 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs866528859, COSV55195491; called by muse, mutect2, varscan2
- SMOC2 | c.556G>A p.E186K (on ENST00000356284 / NM_001166412.2; = p.E197K on NM_022138.3) | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.114); catalogued as rs868464933, COSV100634798; called by muse, mutect2, varscan2
- SON | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99276905; called by muse, mutect2, varscan2
- TEKT2 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV99255387; called by muse, mutect2, varscan2
- TMEM74B | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101121959; called by muse, mutect2, varscan2
- TRIM29 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); catalogued as rs764413015, COSV100531489, COSV59281030; called by muse, mutect2, varscan2
- TRRAP | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62852679; called by muse, mutect2, varscan2
- UNC45B | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99268232; called by muse, mutect2, varscan2
- XIRP2 | c.4802G>A p.G1601E (on ENST00000628543; = p.G1776E on NM_152381.6) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs921843368, COSV54722579; called by muse, mutect2, varscan2
- ACAN | c.7299C>A p.P2433= (on ENST00000560601 / NM_001369268.1; = p.P2357= on NM_001135.3) | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV100717087; called by muse, mutect2, varscan2
- ADGRL2 | c.750C>T p.Y250= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as rs1161518566, COSV99587167; called by muse, mutect2, varscan2
- ASIC4 | c.468C>T p.R156= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs752059801, COSV100761559; called by muse, mutect2, varscan2
- CARMIL3 | c.3618A>G p.P1206= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV99393129; called by muse, mutect2, varscan2
- CD27 | c.768T>C p.P256= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV99868949; called by muse, mutect2, varscan2
- ERCC4 | c.2265C>T p.P755= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs555317161, COSV61312108; called by muse, mutect2, varscan2
- FCGBP | c.2394G>A p.S798= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- GJA8 | c.90C>T p.F30= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV53790617; called by muse, mutect2, varscan2
- HDAC8 | c.219T>C p.D73= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101002344; called by muse, varscan2
- HSPA6 | c.111C>T p.N37= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100553912; called by mutect2, varscan2
- KRTAP21-2 | c.213A>G p.R71= | Silent (SNP) | VAF 85/207 reads (41%) | catalogued as COSV100441097; called by muse, mutect2, varscan2
- MROH5 | c.90C>T p.P30= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs768691163, COSV71302178; called by muse, mutect2, varscan2
- MRPS24 | c.273C>T p.F91= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100451454; called by muse, mutect2, varscan2
- MUC4 | c.13122G>A p.Q4374= (on ENST00000463781 / NM_018406.7; = p.Q138= on NM_004532.6) | Silent (SNP) | VAF 52/73 reads (71%) | catalogued as COSV100203661; called by muse, mutect2, varscan2
- NIPSNAP1 | c.192C>T p.S64= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99331026; called by muse, mutect2, varscan2
- PLCG2 | c.2253C>T p.S751= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1281382289, COSV100842058, COSV63875013; called by muse, mutect2, varscan2
- PLIN3 | c.723C>T p.S241= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV55734506; called by muse, mutect2, varscan2
- RP1L1 | c.1309C>T p.L437= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs1024776979, COSV101222964; called by muse, mutect2, varscan2
- SDK2 | c.6234C>T p.I2078= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV101166849; called by muse, mutect2, varscan2
- STRC | c.366G>A p.Q122= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1489382806, COSV101405393; called by mutect2, varscan2
- SYDE1 | c.2109C>T p.F703= | Silent (SNP) | VAF 117/280 reads (42%) | catalogued as COSV54619408; called by muse, mutect2, varscan2
- TKTL2 | c.972A>C p.T324= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as COSV99761124; called by muse, mutect2, varscan2
- TRBV27 | c.108G>A p.K36= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs752254741; called by muse, mutect2, varscan2
- TRPM2 | c.33G>A p.S11= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs775396387, COSV100308217; called by muse, mutect2, varscan2
- ZNF701 | c.1449G>A p.K483= (on ENST00000301093; = p.K417= on NM_018260.3) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99990682; called by muse, mutect2, varscan2
- LINC02145 | n.458G>A | RNA (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
